Somatic mutation profile of tumor specimen MP2PRT-PAVKER-TMP1-A (aliquot MP2PRT-PAVKER-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVKER, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (755 days).
Specimen MP2PRT-PAVKER-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d704af8-bd92-4905-9e3e-67025a0d1b06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKER-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKER-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2977e36c-a791-4a8f-97ec-612fe56e03eb

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRM4 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 223/568 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs745359442, COSV100946639, COSV65218945; called by muse, mutect2, varscan2
- CCDC88B | c.244_245insATTCCTTACCCCGAG p.R81_G82insDSLPR | In Frame Ins (INS) | VAF 144/482 reads (30%) | called by pindel, varscan2
- ENKUR | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HSD11B1L | c.569G>C p.G190A | Missense Mutation (SNP) | VAF 46/1074 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.622); called by muse, mutect2
- SLF1 | c.2666A>T p.E889V | Missense Mutation (SNP) | VAF 128/321 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNE1 | c.20709C>A p.H6903Q (on ENST00000367255 / NM_182961.4; = p.H6832Q on NM_033071.3) | Missense Mutation (SNP) | VAF 128/324 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROM2 | c.897G>A p.Q299= | Silent (SNP) | VAF 312/753 reads (41%) | called by muse, mutect2, varscan2
- SULT4A1 | c.135C>A p.P45= | Silent (SNP) | VAF 42/892 reads (5%) | called by muse, mutect2
